Gene-level copy-number profile of tumor specimen TCGA-IB-A6UG-01A from TCGA case TCGA-IB-A6UG, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 65.0 years (23,751 days).
Specimen TCGA-IB-A6UG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.10e80c8d-261e-47be-8114-6d911c41ba4a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IB-A6UG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e6c463f3-db31-4054-8bcc-2898adfb4953

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,204; copy number 2: 31,007; copy number 3: 13,778; copy number 4: 1,741; copy number 6: 21; copy number 9: 36; copy number 10: 11; copy number 19: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IB-A6UG-01A-32D-A33S-01): tumor purity 0.22, ploidy 3.32, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 87 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:33,177,492–36,089,389, 43 genes, copy number 6–19 (within-gene range 1–19): NRP1, AL121748.1, RN7SL398P, AL353600.1, AL353600.2, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629, PARD3, Y_RNA, ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1.
- chr18:21,242,242–21,525,417, 1 gene, copy number 9 (within-gene range 1–9): GREB1L.
- chr18:21,380,286–23,026,488, 43 genes, copy number 9–19: AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 12,282. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
